Gene-level copy-number profile of tumor specimen ALCH-AD8I-TTP1-A from ALCHEMIST case ALCH-AD8I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,933 days).
Specimen ALCH-AD8I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e433c3ad-56f6-42d2-b6a5-5b3ae126cfb3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD8I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/12dfcc66-f361-4ec6-b913-e9cc3f51fcad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,243; copy number 2: 53,934; copy number 3: 652; copy number 4: 49; copy number 5: 3; copy number 14: 1; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,503,632–222,519,732, 2 genes (within-gene range 0–2): RNU6-791P, AL592148.2.
- chr2:114,122,274–114,123,293, 1 gene: AC010982.1.
- chr2:236,153,071–236,153,172, 1 gene: Y_RNA.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr12:34,162,477–34,166,954, 2 genes: AC140847.3, TUBB8P4.
- chr12:34,205,699–34,209,675, 2 genes (within-gene range 0–1): RNA5SP357, DUX4L27.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:33,064,569–33,089,696, 3 genes, copy number 5: HLA-DPA1, HLA-DPB1, RPL32P1.
- chr14:105,597,691–105,601,728, 1 gene, copy number 17 (within-gene range 2–17): IGHE.
- chr19:1,238,179–1,239,522, 1 gene, copy number 14: AC004221.1.

Autosomal genes at a single copy (total copy number 1): 1,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
